Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GT, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GT-06A (Metastatic).

DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

FNB +ve node (L) axilla (melanoma back ...excision
axillary contents. Histology.

Refer :

(L)

Melanoma tumour banking has been taken by

Consent form:

MACROSCOPIC DESCRIPTION

(Dr

"AXILLARY DISSECTION LEFT AXILLA". A piece of fatty tissue 120 x 75 x 25mm with attached muscular tissue measuring 75 x 60 x 20mm. Altogether the specimen measures 190g. Multiple lymph nodes are identified measuring from 3 to 27mm in maximal dimension. Lymph nodes embedded from one end to the other.

- A. Two nodes.
- B. A bisected node (a slice has been taken for
- C. One node.
- D. Two node.
- E-F. One node bisected.
- G-L. Two nodes in each.

12A-0-3

Melanoma NOS 8720/3

Site: lymph node, Axilla

C 77.3

lw 6/10/11

MICROSCOPIC REPORT

Metastatic melanoma is present in only one (1B) of the 16 lymph nodes identified.
There is focal invasion of the node capsule but no definite extranodal spread.

SUMMARY

Lymph nodes left axilla - Metastatic melanoma (1/16)

REPORTED BY:

Source: NCI Genomic Data Commons file 6ff84ce2-17d3-4704-b73b-6a11a3d3c06c (TCGA-EE-A2GT.EB8A3520-4249-4DF4-AC19-80B4C9599974.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).